MMRF case MMRF_2229 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/96342ad0-5028-4c81-88ac-ee61414c585a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.8 years (25,863 days); ISS stage: I; Days to last known disease status: 827 days (2.3 years); Days to last follow up: 827 days (2.3 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 239 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 28 days.
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 250 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 29 days; Days to treatment end: 225 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 337 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 533 days (1.5 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -61 (ECOG 0): M Protein 5.57 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.2 mg/dL; Immunoglobulin G 68.5 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 2.21 µg/mL; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 11.7 g/dL; Glucose 5.28 mmol/L; C-Reactive Protein 0.08 mg/dL.
- Day 29 (ECOG 0): M Protein 2.71 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.113 mg/dL; Immunoglobulin G 31 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.34 g/L; Beta 2 Microglobulin 1.79 µg/mL; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 5.77 mmol/L; Leukocytes 9.6 ×10⁹/L; Absolute Neutrophil 6.1 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 8.2 g/dL; Glucose 5.17 mmol/L.
- Day 113 (ECOG 0): M Protein 0.59 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.898 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.108 mg/dL; Immunoglobulin G 9.27 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.5 g/L; Beta 2 Microglobulin 3.54 µg/mL; Lactate Dehydrogenase 4.25 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 12.5 ×10⁹/L; Absolute Neutrophil 10 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 117 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 5.12 mmol/L.
- Day 197 (ECOG 0): M Protein 0.38 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.953 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.082 mg/dL; Immunoglobulin G 5.45 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.47 g/L; Beta 2 Microglobulin 1.49 µg/mL; Lactate Dehydrogenase 6.08 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 11.7 ×10⁹/L; Absolute Neutrophil 9.8 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 6.4 g/dL; Glucose 4.24 mmol/L.
- Day 313 (ECOG 1): M Protein 0.23 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.206 mg/dL; Immunoglobulin G 6.52 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.77 g/L; Beta 2 Microglobulin 2.34 µg/mL; Lactate Dehydrogenase 4.18 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 6.2 g/dL; Glucose 4.84 mmol/L.
- Day 393 (ECOG 0): M Protein 0.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.63 mg/dL; Immunoglobulin G 7.49 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.83 g/L; Beta 2 Microglobulin 2.7 µg/mL; Lactate Dehydrogenase 3.58 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 251 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 44 g/L; Total Protein 6.9 g/dL; Glucose 5.23 mmol/L.
- Day 477 (ECOG 0): M Protein 0.23 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.691 mg/dL; Immunoglobulin G 8.72 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.55 g/L; Beta 2 Microglobulin 2.83 µg/mL; Lactate Dehydrogenase 3.77 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 4.95 mmol/L.
- Day 564 (ECOG 1): M Protein 0.41 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.558 mg/dL; Immunoglobulin G 8.71 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.46 g/L; Beta 2 Microglobulin 3.12 µg/mL; Lactate Dehydrogenase 4.82 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 145 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 4.84 mmol/L.
- Day 655 (ECOG 0): M Protein 0.27 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.493 mg/dL; Immunoglobulin G 5.99 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.43 g/L; Beta 2 Microglobulin 2.77 µg/mL; Lactate Dehydrogenase 4 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 138 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 4.84 mmol/L.
- Day 743 (ECOG 0): M Protein 0.28 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.485 mg/dL; Immunoglobulin G 3.6 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 2.93 µg/mL; Lactate Dehydrogenase 3.9 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 136 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.03 mmol/L; Albumin 38 g/L; Total Protein 5.9 g/dL; Glucose 3.91 mmol/L.
- Day 827 (ECOG 0): M Protein 0.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.619 mg/dL; Immunoglobulin G 7.82 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 3.52 µg/mL; Lactate Dehydrogenase 4.37 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 144 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 4.07 mmol/L.

Other clinical attributes
- Day -61: Weight: 75 kg; Height: 165 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Prostate Cancer.

Biospecimens (2 samples)
- Sample MMRF_2229_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -61 days.
- Sample MMRF_2229_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -61 days.
